Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5JL, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5JL-01A (Primary Tumor).

[page 1 of 2]
ICD-0-3

Carcinoma, adrenal cortical w/
oncocytic cytologic features
Site: (R) Adrenal Gland, cortex C74.0
8370/3
910 21/13

Specimen(s) Received

Right adrenal gland

Clinical History

Right adrenal tumour; production of testosterone and androgens – right adrenalectomy; ? ACC; ? Adrenal cortical adenoma

Macroscopic Description

The specimen consists of a previously incised adrenal gland weighing 28g and measuring 65 x 30 x 30mm with a rounded medullary nodule 38 x 34 x 30mm with a grey / brown cut surface. The adjacent cortex shows no nodularity. A – Representative sections taken.

Microscopic Description

Sections of adrenal gland show a well circumscribed nodule composed of focally markedly pleomorphic epithelial cells (see photograph) with abundant foamy, oncocytic cytoplasm and only occasional areas of clear cells. Up to 6 mitoses per 50HPF are present with occasional atypical mitoses. No capsular, sinusoidal or vascular invasion is seen. Excision appears complete.

COMMENT : The appearances are most consistent with an adrenal cortical carcinoma.

Dr. [redacted] reports

The adrenal lesion is a LOW GRADE ADRENAL CORTICAL CARCINOMA. The malignant cells display oncocytic cytological features. The tumour demonstrates 5 of the Weiss criteria of malignancy comprising a mitotic rate of 6 per 50hpf, atypical mitoses, a diffuse growth pattern, cytological atypia and eosinophilic cytoplasm. There is no vascular or sinusoidal invasion. There is no extra-adrenal spread. There is no coagulative necrosis. There is no perineural growth. Based on these slides local excision appears complete.

Immunohistochemistry is as follows:

K1-67 proliferation index : 8%

IGF2: Diffusely positive (perinuclear dot-like pattern)

Glycocorticoid receptor: Strongly diffusely (4+) positive

This immunohistochemical profile is typical of adrenal cortical carcinoma and further supports the diagnosis of malignancy.

Final Summary

ADRENAL GLAND, RIGHT

ADRENAL CORTICAL CARCINOMA;
MARGINS CLEAR

[page 2 of 2]
Requesting Doctor's Information:

Report To:

Received 12/20/13

HISTOPATHOLOGY FOR REVIEW

MICROSCOPIC:

The adrenal lesion is a **LOW GRADE ADRENAL CORTICAL CARCINOMA**. The malignant cells display **oncocytic** cytological features. The tumour demonstrates 5 of the Weiss criteria of malignancy comprising a mitotic rate of 6 per 50 hpf, atypical mitoses, a diffuse growth pattern, cytological atypia and eosinophilic cytoplasm. There is no vascular or sinusoidal invasion. There is no extra-adrenal spread. There is no coagulative necrosis. There is no perineural growth. Based on these slides local excision appears complete.

Immunohistochemistry is as follows:

KI-67 proliferative index: 8%

IGF2: Diffusely positive (perinuclear dot-like pattern)

Glucoocorticoid receptor: Strongly diffusely (4+) positive

This immunohistochemical profile is typical of adrenal cortical carcinoma and further supports the diagnosis of malignancy.

SUMMARY:

Adrenal gland: Adrenal cortical carcinoma.

REPORTING PATHOLOGIST:

(Electronic Signature)

Case is (chief):		

12/23/13

12/17/13

Source: NCI Genomic Data Commons file c9f9dc8b-68ca-4a7e-be69-4d23df5a51a1 (TCGA-OR-A5JL.BD8435C3-C525-472C-8B43-EC2CAE22B785.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).